Somatic mutation profile of tumor specimen TCGA-KK-A8IJ-01A (aliquot TCGA-KK-A8IJ-01A-11D-A34U-08) from TCGA case TCGA-KK-A8IJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.7 years (21,793 days).
Specimen TCGA-KK-A8IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53ae9a58-616d-468f-a1df-441dc2b7ad06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IJ-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IJ-11A-11D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c01519c8-8623-4ea6-8fb8-e4c193596e52

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Del 2, Splice Site 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.2696A>T p.Y899F (on ENST00000506720 / NM_001322402.2; = p.Y831F on NM_015236.6) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV101546926; called by muse, mutect2
- BANK1 | c.2142T>G p.I714M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100536032; called by muse, mutect2, varscan2
- CCDC82 | c.446A>C p.Q149P | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99567146; called by muse, varscan2
- CD160 | c.435A>C p.Q145H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99353347; called by muse, mutect2, varscan2
- CEMIP2 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs763962057, COSV100987082; called by muse, mutect2, varscan2
- CFAP94 | c.1082A>G p.N361S (on ENST00000320267 / NM_001352064.2; = p.N367S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV100209080; called by muse, mutect2, varscan2
- CSMD2 | c.9165T>G p.N3055K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99587370; called by muse, mutect2, varscan2
- EML5 | c.2985A>G p.G995= | Splice Region (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100715238; called by muse, mutect2, varscan2
- FNIP1 | c.3457G>A p.V1153I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.069); catalogued as COSV100330319; called by muse, mutect2, varscan2
- HMCN1 | c.9363+1G>A p.X3121_splice | Splice Site (SNP) | VAF 24/91 reads (26%) | catalogued as COSV99625914; called by muse, mutect2, varscan2
- HMGCR | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99843091; called by muse, mutect2, varscan2
- IQUB | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.07); catalogued as COSV61240214; called by muse, mutect2
- LZTS3 | c.1825A>C p.K609Q (on ENST00000329152; = p.K563Q on NM_001282533.2) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99417573; called by muse, varscan2
- PCDHA1 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs577194073, COSV100974318; called by muse, mutect2, varscan2
- PSMC2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1239171805, COSV53007529; called by muse, mutect2, varscan2
- RYR3 | c.4699G>A p.A1567T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs748141606, COSV66776672; called by muse, mutect2
- SMURF2 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99300472; called by muse, mutect2, varscan2
- TJAP1 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446302, COSV99446479; called by muse, mutect2, varscan2
- ZNF823 | c.1526G>T p.S509I (on ENST00000341191 / NM_001297610.2; = p.S465I on NM_017507.2) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.538); catalogued as COSV100362446; called by muse, mutect2, varscan2
- ICE2 | c.1564del p.I522Lfs*9 | Frame Shift Del (DEL) | VAF 14/107 reads (13%) | called by mutect2, pindel, varscan2
- NUMA1 | c.5120del p.L1707* | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- BYSL | c.39G>A p.Q13= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV99539751; called by muse, mutect2, varscan2
- NLRP4 | c.1209T>A p.A403= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100015845; called by muse, mutect2
- PACSIN3 | c.387C>T p.S129= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PTCH2 | c.1023T>A p.I341= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100941978; called by muse, mutect2
- SLITRK3 | c.1485C>T p.I495= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99578772; called by muse, mutect2, varscan2
- SUGP2 | c.2502G>A p.V834= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV100431640; called by muse, mutect2, varscan2
- URB2 | c.2958T>A p.L986= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV99270858; called by muse, mutect2, varscan2
- UVSSA | c.*8915T>A | 3'UTR (SNP) | VAF 39/398 reads (10%) | catalogued as rs199774688; called by muse, varscan2
